Somatic mutation profile of tumor specimen TCGA-JX-A3PZ-01A (aliquot TCGA-JX-A3PZ-01A-11D-A21Q-09) from TCGA case TCGA-JX-A3PZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 25.5 years (9,303 days).
Specimen TCGA-JX-A3PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b3ead2d-ae6a-4cd1-b351-d447d9921107.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JX-A3PZ-10A (Blood Derived Normal), aliquot TCGA-JX-A3PZ-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a8bec12-0922-4c4b-a9ba-ba197ab79ebf

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SNRPD3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 30/58 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53183301, COSV53184122; called by muse, mutect2, varscan2
- ABCA7 | c.2591C>G p.S864C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54038202; called by muse, mutect2, varscan2
- AC004593.2 | c.1463T>G p.V488G | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV56102582; called by muse, mutect2, varscan2
- APOBEC3G | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as rs142694979; called by muse, mutect2, varscan2
- AR | c.2202G>C p.Q734H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM983649, COSV65964532; called by muse, mutect2, varscan2
- ATP10A | c.2233G>A p.V745I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs372138642; called by muse, mutect2, varscan2
- BCR | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100007026; called by muse, mutect2, varscan2
- CAMK1 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56540587; called by muse, mutect2, varscan2
- CEP192 | c.6728C>G p.S2243C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.363); catalogued as COSV58071346; called by muse, mutect2, varscan2
- CFHR5 | c.1571G>A p.R524K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56825212; called by muse, mutect2, varscan2
- DFFA | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV63063930; called by muse, mutect2, varscan2
- DYNC2H1 | c.10876G>A p.V3626M | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs201852557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1060501079, COSV57321058; called by muse, mutect2, varscan2
- HEATR1 | c.3773G>A p.C1258Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63983384; called by muse, mutect2
- KCNQ1 | c.1278C>G p.D426E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV50134971; called by muse, mutect2, varscan2
- KTN1 | c.1625C>G p.S542* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV68025925; called by muse, mutect2, varscan2
- LRRK2 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV54173239; called by muse, mutect2, varscan2
- MDC1 | c.5524G>A p.E1842K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV64528184; called by muse, mutect2, varscan2
- MKI67 | c.5188G>A p.E1730K | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.358); catalogued as rs534656691, COSV100896966; called by muse, mutect2, varscan2
- MYL9 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs768626963, COSV54073066, COSV99640907; called by muse, mutect2, varscan2
- NCAN | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99388273; called by muse, mutect2, varscan2
- NLRP8 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV52594765; called by muse, mutect2, varscan2
- NOL6 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs200677942, COSV99955179; called by muse, mutect2, varscan2
- NOP56 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV61391852; called by muse, mutect2, varscan2
- NSD1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.614); catalogued as COSV61785916; called by muse, mutect2, varscan2
- OR10Z1 | c.265dup p.D89Gfs*23 | Frame Shift Ins (INS) | VAF 14/106 reads (13%) | catalogued as rs752054889; called by mutect2, varscan2
- RAD9B | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV63778973; called by muse, mutect2, varscan2
- RAPH1 | c.2634G>T p.M878I | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99864454; called by muse, mutect2, varscan2
- RASAL2 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62724402; called by muse, mutect2, varscan2
- SLC34A2 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs78448446, COSV65943312; called by muse, mutect2, varscan2
- SLITRK1 | c.1400T>C p.F467S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65677852; called by muse, mutect2, varscan2
- TMEM117 | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56919974; called by muse, mutect2, varscan2
- TMEM184C | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV56855183; called by muse, mutect2, varscan2
- USP1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.946); catalogued as COSV60575732; called by muse, mutect2, varscan2
- ZNF174 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51902650, COSV51904576; called by muse, mutect2, varscan2
- ZNF492 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1287247129, COSV71762428; called by muse, mutect2
- BVES | c.327G>A p.S109= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs139347341; called by muse, mutect2, varscan2
- CNBD1 | c.660A>G p.G220= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1444125466, COSV72976760; called by muse, mutect2, varscan2
- CNTN2 | c.2295C>A p.G765= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs1265642245, COSV59353462; called by muse, mutect2, varscan2
- CTTN | c.630C>T p.A210= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs1170897968, COSV100097867, COSV57230900; called by muse, mutect2, varscan2
- FOXR2 | c.183G>A p.Q61= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV59259258; called by muse, mutect2, varscan2
- HSPG2 | c.8574C>T p.V2858= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs1193299964, COSV65977985; called by muse, mutect2, varscan2
- ITGA11 | c.1482G>C p.V494= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV59878754, COSV59882457; called by muse, mutect2, varscan2
- KLK14 | c.165C>T p.A55= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV50071598; called by muse, mutect2, varscan2
- MAP1LC3A | c.219G>C p.L73= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54166987; called by muse, mutect2, varscan2
- PAK5 | c.513C>T p.H171= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs1285260824, COSV62031894; called by muse, mutect2, varscan2
- PRAG1 | c.2463G>A p.V821= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV58167609; called by mutect2, varscan2
- RBM12 | c.735G>A p.P245= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs780857714, COSV58294776; called by muse, mutect2, varscan2
- TMEM52B | c.345C>A p.I115= (on ENST00000381923 / NM_001079815.1; = p.I95= on NM_153022.4) | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV53729887; called by muse, mutect2, varscan2
- VPS16 | c.2086C>T p.L696= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV66799694; called by muse, mutect2, varscan2
- WRNIP1 | c.1317C>T p.D439= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1186677062, COSV66356099; called by muse, mutect2, varscan2
- Z83844.2 | c.687C>T p.I229= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs779047496, COSV60929913; called by muse, mutect2, varscan2
- CABP1 | c.655-3620G>A | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as COSV56460656; called by muse, mutect2, varscan2
- MIR668 | n.10G>A | RNA (SNP) | VAF 21/32 reads (66%) | catalogued as rs750767425; called by muse, mutect2, varscan2
